Somatic mutation profile of tumor specimen TCGA-FD-A3SS-01A (aliquot TCGA-FD-A3SS-01A-12D-A22Z-08) from TCGA case TCGA-FD-A3SS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.8 years (24,408 days).
Specimen TCGA-FD-A3SS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a6b751d-a5ee-492d-830a-f11792a243a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SS-10A (Blood Derived Normal), aliquot TCGA-FD-A3SS-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1791d896-ccbe-472b-ba16-d294e7f8a99f

The open-access MAF lists 528 somatic variants for this specimen: 382 protein-altering or splice-affecting, 134 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 336, Silent 134, Nonsense Mutation 30, Splice Site 7, Frame Shift Del 7, Intron 5, RNA 4, 5'UTR 2, 3'Flank 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 49/65 reads (75%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.4342C>G p.L1448V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs775920669, COSV70039737; called by muse, mutect2, varscan2
- ABCA2 | c.4331-1G>A p.X1444_splice (on ENST00000614293; = p.X1414_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV55804562, COSV55804672; called by muse, mutect2, varscan2
- ABCB1 | c.2413G>A p.D805N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV55951709, COSV55958888; called by muse, mutect2
- ABCC1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866613558, COSV60691211; called by muse, mutect2
- ABCC3 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs376037553; called by muse, mutect2, varscan2
- AC100868.1 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV51847790; called by muse, mutect2, varscan2
- ACBD7 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1426126348, COSV62252732; called by muse, mutect2
- ACCS | c.557-1G>A p.X186_splice | Splice Site (SNP) | VAF 22/119 reads (18%) | catalogued as COSV55459603; called by muse, mutect2, varscan2
- ACLY | c.2155-1G>T p.X719_splice | Splice Site (SNP) | VAF 27/67 reads (40%) | catalogued as COSV61252086; called by muse, mutect2, varscan2
- ACOX1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs780812320, COSV53131399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR1B | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56705308; called by muse, mutect2, varscan2
- ACTR8 | c.1852G>C p.E618Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51637940; called by muse, mutect2, varscan2
- ADAM18 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 7/105 reads (7%) | catalogued as rs1427102051, COSV55851286; called by muse, mutect2
- ADAMTS16 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.253); catalogued as COSV57001161; called by muse, mutect2, varscan2
- ADAMTS20 | c.3160C>T p.H1054Y | Missense Mutation (SNP) | VAF 66/109 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.438); catalogued as COSV67136505; called by muse, mutect2, varscan2
- ADAMTS20 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs1434150093, COSV67125673, COSV67136081, COSV67136513; called by muse, mutect2, varscan2
- ADCY4 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222723362, COSV60256442; called by muse, mutect2, varscan2
- ADRB2 | c.1188C>A p.S396R | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.037); catalogued as COSV60006008; called by muse, mutect2, varscan2
- AFF2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.058); catalogued as COSV60683052; called by muse, mutect2
- AFF3 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408348694, COSV57865858; called by muse, mutect2, varscan2
- AGPS | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV51567526, COSV51569866; called by muse, mutect2
- AGRN | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV65071538; called by muse, varscan2
- AHNAK2 | c.8360G>C p.R2787T | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV60924515; called by muse, mutect2, varscan2
- AJUBA | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV52986237; called by muse, mutect2, varscan2
- AKAP8L | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV68474166; called by muse, mutect2, varscan2
- AKNAD1 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV64173062; called by muse, mutect2, varscan2
- ALB | c.1634G>A p.R545K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774108516, COSV55740856; called by muse, mutect2, varscan2
- ALDH1L1 | c.2341C>T p.R781W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1333230358, COSV56417478, COSV99857204; called by muse, mutect2, varscan2
- ANK3 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV55073287; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7445C>G p.S2482C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV51854782; called by muse, mutect2, varscan2
- AP1G1 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55493529; called by muse, mutect2, varscan2
- APC | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 38/56 reads (68%) | catalogued as COSV57327935, COSV99965567; called by muse, mutect2, varscan2
- APOB | c.6235G>A p.E2079K | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.037); catalogued as COSV51946085; called by muse, mutect2, varscan2
- APOBEC4 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58018135; called by muse, mutect2, varscan2
- APOL1 | c.372G>A p.M124I | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.258); catalogued as rs1236066328, COSV59869591; called by muse, mutect2, varscan2
- ARFGEF1 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs769150403; called by muse, mutect2, varscan2
- ARHGEF15 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs867056869, COSV62725961; called by muse, mutect2, varscan2
- ARMC6 | c.1485G>C p.Q495H (on ENST00000392336; = p.Q470H on NM_033415.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV54183359; called by muse, mutect2, varscan2
- ARMH4 | c.1299C>G p.F433L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV50769260; called by muse, varscan2
- ASXL2 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55464460; called by muse, mutect2
- ASXL3 | c.3824C>T p.S1275F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV52474547; called by muse, mutect2
- ATAD5 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV58977343; called by muse, mutect2, varscan2
- ATP10D | c.3670G>A p.D1224N | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV56711130; called by muse, mutect2, varscan2
- ATP11B | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as COSV60031701; called by muse, mutect2, varscan2
- ATP12A | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762399901, COSV54518642; called by muse, mutect2, varscan2
- ATP1B2 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51516252; called by muse, mutect2, varscan2
- ATP2A2 | c.2030G>C p.R677P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875265, COSV57876016; called by muse, mutect2, varscan2
- ATP5PF | c.138G>T p.K46N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV53167615; called by muse, mutect2, varscan2
- BCL6B | c.28G>C p.A10P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as COSV53428982; called by muse, mutect2, varscan2
- BMPR1A | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.752); catalogued as rs756541429, COSV63135328; called by muse, mutect2, varscan2
- BRCA2 | c.6772G>A p.E2258K | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs730881549, CM125548, COSV66448056; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- C14orf93 | c.1591G>C p.E531Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.225); catalogued as COSV52984789; called by muse, mutect2
- C18orf54 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 26/90 reads (29%) | catalogued as rs1343433274; called by muse, mutect2, varscan2
- C1orf198 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV64176135; called by muse, mutect2, varscan2
- C1orf87 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV100966984, COSV64598090; called by muse, mutect2, varscan2
- C2CD3 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58097619; called by muse, varscan2
- C4BPA | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV65537378; called by muse, mutect2, varscan2
- CAST | c.1204C>T p.P402S (on ENST00000341926; = p.P485S on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV57788292; called by muse, mutect2, varscan2
- CCDC102B | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.341); catalogued as COSV60149803; called by muse, mutect2, varscan2
- CCDC171 | c.3651C>G p.I1217M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV66242587; called by muse, mutect2, varscan2
- CCDC27 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 130/393 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.042); catalogued as COSV53902233; called by muse, mutect2, varscan2
- CCDC63 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57530006; called by muse, mutect2
- CD2AP | c.1229C>G p.P410R | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV63762166; called by muse, mutect2, varscan2
- CDC45 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54247467; called by muse, mutect2
- CDCP2 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61285189; called by muse, mutect2, varscan2
- CELSR1 | c.2901G>T p.W967C | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV53096347; called by muse, mutect2, varscan2
- CEP120 | c.2053G>A p.E685K | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV60267418; called by muse, mutect2
- CHAMP1 | c.1328C>T p.S443L | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV63522904; called by muse, mutect2, varscan2
- CHGB | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs868039492, COSV100972954, COSV66759464; called by muse, mutect2
- CLEC5A | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs782227023, COSV69397810; called by muse, mutect2, varscan2
- CNDP2 | c.1233G>C p.L411F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as rs749779594, COSV60840995; called by muse, mutect2, varscan2
- CNTN6 | c.1022C>G p.A341G | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63183290; called by muse, mutect2, varscan2
- CNTN6 | c.1784G>C p.R595T | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63183295; called by muse, mutect2
- CNTNAP2 | c.2944G>C p.E982Q | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62231981; called by muse, mutect2, varscan2
- CNTRL | c.2233G>C p.E745Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV53051235; called by muse, mutect2, varscan2
- COG4 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as COSV100091090; called by muse, mutect2
- COG5 | c.1329G>C p.L443F | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV51759452; called by muse, mutect2, varscan2
- COL22A1 | c.2828G>T p.G943V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57351680; called by muse, mutect2, varscan2
- COL6A6 | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1409232313, COSV62032965; called by muse, mutect2, varscan2
- COLGALT2 | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100730270; called by muse, mutect2
- CPEB1 | c.347G>A p.R116Q (on ENST00000617958; = p.R56Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs761900804, COSV71604671; called by muse, mutect2, varscan2
- CPLX1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58375861; called by muse, mutect2, varscan2
- CRAT | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV58878421; called by muse, mutect2
- CREBZF | c.1010C>T p.S337L | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52630371; called by muse, mutect2, varscan2
- CRYGN | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61564220; called by muse, mutect2, varscan2
- CSMD1 | c.8660G>C p.R2887T (on ENST00000520002; = p.R2886T on NM_033225.6) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.02); catalogued as COSV59360016; called by muse, mutect2, varscan2
- CTNNAL1 | c.691C>T p.L231F | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57704557; called by muse, mutect2, varscan2
- CTNND2 | c.1896del p.N634Tfs*9 | Frame Shift Del (DEL) | VAF 51/147 reads (35%) | catalogued as COSV58911984; called by mutect2, pindel, varscan2
- DCAF4L2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.233); catalogued as rs764483453, COSV60476507; called by muse, mutect2, varscan2
- DDIAS | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61272867; called by muse, mutect2, varscan2
- DDX54 | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV58375288; called by muse, mutect2, varscan2
- DENND4C | c.1828C>T p.R610C | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983170908, COSV66821954; called by muse, mutect2, varscan2
- DHRS9 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV59141027; called by muse, mutect2, varscan2
- DKK4 | c.356C>T p.P119L | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.476); catalogued as COSV55183290; called by muse, mutect2, varscan2
- DLGAP5 | c.2231G>C p.G744A | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV55964645; called by muse, mutect2, varscan2
- DMC1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53260224; called by muse, mutect2, varscan2
- DMD | c.4801G>C p.E1601Q | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); catalogued as COSV63778547; called by muse, mutect2
- DNAH5 | c.878G>C p.R293T | Missense Mutation (SNP) | VAF 32/247 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV54218183, COSV54242819; called by muse, mutect2, varscan2
- DNASE1L3 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59157014; called by muse, mutect2, varscan2
- DRG1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs28369552, COSV58919520; called by muse, mutect2, varscan2
- DUSP12 | c.981G>T p.M327I | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771719059, COSV63411584, COSV63411723; called by muse, mutect2, varscan2
- EDAR | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757450239, COSV51500429; called by muse, mutect2, varscan2
- EIF2AK4 | c.1584G>C p.W528C | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55472316; called by muse, mutect2
- EN1 | c.1092C>G p.I364M | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs769343130, COSV54632229; called by muse, mutect2, varscan2
- EP400 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV57781434; called by muse, mutect2, varscan2
- EPHX4 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.3); catalogued as COSV64889851; called by muse, mutect2, varscan2
- ERICH3 | c.667C>G p.Q223E | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV58599236; called by muse, mutect2, varscan2
- ERMARD | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64651225; called by muse, mutect2, varscan2
- EVC | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as COSV53836410, COSV99382164; called by muse, mutect2, varscan2
- EVI5 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV63278764; called by muse, mutect2
- FANCD2 | c.935T>G p.L312W | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55043598; called by muse, mutect2, varscan2
- FLNA | c.1568-1G>C p.X523_splice | Splice Site (SNP) | VAF 5/85 reads (6%) | catalogued as COSV61048610; called by muse, mutect2
- G2E3 | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as COSV52842059; called by muse, mutect2, varscan2
- GABRB3 | c.1324C>G p.L442V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.085); catalogued as COSV100158669, COSV54676970; called by muse, mutect2, varscan2
- GABRP | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV54661174; called by muse, mutect2, varscan2
- GAD1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.621); catalogued as rs987723157; called by muse, mutect2
- GATA5 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV53347043; called by muse, mutect2, varscan2
- GATA6 | c.1559C>G p.S520C | Missense Mutation (SNP) | VAF 83/138 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV52527047; called by muse, mutect2, varscan2
- GDPD3 | c.543G>T p.K181N | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.372); catalogued as COSV53775603; called by muse, mutect2, varscan2
- GJA1 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56998151, COSV56999022; called by muse, mutect2, varscan2
- GLUD2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100046844; called by muse, mutect2, varscan2
- GMIP | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52555120; called by muse, mutect2, varscan2
- GNAL | c.952G>A p.D318N (on ENST00000269162 / NM_001142339.3; = p.D395N on NM_182978.4) | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV52331678; called by muse, mutect2
- GPAT3 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV52356150; called by muse, mutect2, varscan2
- GRM8 | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.251); catalogued as COSV58853712; called by muse, mutect2
- H2AC21 | c.50C>G p.S17W | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV100479653, COSV58612794; called by muse, mutect2, varscan2
- HASPIN | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV53997754; called by muse, mutect2, varscan2
- HCCS | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV100335590; called by muse, mutect2
- HEPHL1 | c.2134C>G p.Q712E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV100244551, COSV59894773; called by muse, mutect2, varscan2
- HIPK4 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as COSV52524376; called by muse, mutect2
- HMCN1 | c.11056G>A p.D3686N | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54926245; called by muse, mutect2, varscan2
- HNRNPK | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61090520; called by muse, mutect2, varscan2
- HNRNPU | c.1643C>G p.P548R (on ENST00000283179; = p.P610R on NM_004501.3) | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51693108; called by muse, mutect2, varscan2
- HPS3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs1411753545, COSV56056450; called by muse, mutect2, varscan2
- HSD17B13 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.439); catalogued as rs1436194289, COSV56346883; called by muse, mutect2, varscan2
- HSP90AA1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99354950; called by muse, mutect2
- HSPG2 | c.6874C>T p.R2292C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1405964612, COSV65975102; called by muse, mutect2, varscan2
- HTATSF1 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV99511357; called by muse, mutect2, varscan2
- HTR3E | c.1337C>G p.S446C (on ENST00000415389 / NM_001256613.1; = p.S461C on NM_182589.2) | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58948221; called by muse, mutect2, varscan2
- HTT | c.3247C>G p.L1083V | Missense Mutation (SNP) | VAF 16/461 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV61866645; called by muse, mutect2
- ICMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59474233; called by muse, mutect2, varscan2
- IFIT2 | c.979G>A p.D327N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.153); catalogued as rs763699307, COSV51080124; called by muse, mutect2, varscan2
- IFT140 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV68493318; called by muse, mutect2, varscan2
- IL2RA | c.56G>A p.C19Y | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56922083; called by muse, mutect2
- IL31RA | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs778819834, COSV104396477; called by muse, mutect2, varscan2
- INO80 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.108); catalogued as COSV62741048; called by muse, mutect2
- INSC | c.605A>C p.Q202P | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV65412329; called by muse, mutect2, varscan2
- INTS2 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52151683, COSV52155421; called by muse, mutect2, varscan2
- IPP | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV63433374; called by muse, mutect2, varscan2
- ITGB1 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as COSV100171262, COSV56485064; called by muse, mutect2, varscan2
- ITSN2 | c.2666C>T p.S889L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV61951820; called by muse, mutect2, varscan2
- JARID2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV59192719; called by muse, mutect2, varscan2
- KAT6A | c.191C>G p.S64* | Nonsense Mutation (SNP) | VAF 28/239 reads (12%) | catalogued as COSV99704419, COSV99705273; called by muse, mutect2, varscan2
- KCTD6 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV100250086; called by muse, mutect2, varscan2
- KCTD8 | c.1320del p.M440Ifs*44 | Frame Shift Del (DEL) | VAF 30/154 reads (19%) | catalogued as COSV63591702, COSV63593631; called by pindel, varscan2
- KDM5B | c.3424-1G>C p.X1142_splice | Splice Site (SNP) | VAF 23/176 reads (13%) | catalogued as COSV52511009; called by muse, mutect2, varscan2
- KIDINS220 | c.5173C>T p.Q1725* | Nonsense Mutation (SNP) | VAF 21/84 reads (25%) | catalogued as COSV56760194; called by muse, mutect2, varscan2
- KIF1B | c.883-1G>C p.X295_splice (on ENST00000377086 / NM_001365952.1; = p.X289_splice on NM_015074.3) | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV55813127, COSV99823533; called by muse, mutect2, varscan2
- KLHL20 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52943973; called by muse, mutect2
- L3MBTL1 | c.780G>C p.E260D (on ENST00000418998 / NM_001377303.1; = p.E170D on NM_015478.7) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as COSV64234030; called by muse, mutect2, varscan2
- L3MBTL3 | c.1149G>C p.K383N | Missense Mutation (SNP) | VAF 64/368 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100695937, COSV62387880; called by muse, mutect2, varscan2
- LCOR | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.041); catalogued as COSV53717662; called by muse, mutect2
- LOXL1 | c.1543G>A p.D515N | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV56095467; called by muse, mutect2
- LPP | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs751571549, COSV57106786; called by muse, mutect2, varscan2
- LRRC36 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52081350; called by muse, mutect2
- LRRN1 | c.1160C>T p.T387I | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs145675446, COSV60015410; called by muse, mutect2, varscan2
- LRRTM1 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV54438041, COSV54444905; called by muse, mutect2, varscan2
- LRWD1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52961644, COSV99479334; called by muse, mutect2, varscan2
- LUC7L | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV53459936; called by muse, mutect2, varscan2
- LUZP2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs763936231, COSV61213537; called by muse, mutect2, varscan2
- MAPK3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV53775626; called by muse, mutect2, varscan2
- MARCHF7 | c.1728G>C p.L576F | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52030371; called by muse, mutect2, varscan2
- MAVS | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV63927332; called by muse, varscan2
- MED15 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.944); catalogued as COSV53032073; called by muse, mutect2
- MRGPRF | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV57995441, COSV57996337; called by muse, mutect2
- MTMR8 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV66395543; called by muse, mutect2, varscan2
- MYH10 | c.2178G>C p.Q726H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.957); catalogued as COSV52607309, COSV52609878; called by muse, mutect2, varscan2
- MYH9 | c.2743G>A p.E915K | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV53391069; called by muse, mutect2, varscan2
- MYLK2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV65659688; called by muse, mutect2, varscan2
- MYO1B | c.2867C>T p.P956L (on ENST00000304164; = p.P898L on NM_012223.5) | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); catalogued as rs1448829591, COSV58435815; called by muse, mutect2, varscan2
- MYO5B | c.1132C>T p.H378Y | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV53226605; called by muse, mutect2, varscan2
- MYT1L | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV67721392, COSV67728299, COSV67729946; called by muse, mutect2
- NAP1L2 | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.473); catalogued as COSV65172880; called by muse, mutect2
- NASP | c.2069del p.S690* | Frame Shift Del (DEL) | VAF 70/216 reads (32%) | catalogued as COSV59648017; called by mutect2, pindel, varscan2
- NCLN | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV55743349; called by muse, mutect2, varscan2
- NCOA1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV56050295; called by muse, varscan2
- NCOA1 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV56045398, COSV56050311; called by muse, varscan2
- NCSTN | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV54185520, COSV54189353; called by muse, mutect2, varscan2
- NCSTN | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV54190326; called by muse, mutect2, varscan2
- NEIL2 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.601); catalogued as COSV52707488; called by muse, mutect2, varscan2
- NFKBIZ | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV58201474; called by muse, mutect2, varscan2
- NID2 | c.1251C>A p.N417K | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as COSV53494546, COSV53500657; called by muse, mutect2, varscan2
- NOMO1 | c.3645G>C p.K1215N | Missense Mutation (SNP) | VAF 90/649 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55060464; called by muse, mutect2, varscan2
- NOP14 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 16/339 reads (5%) | catalogued as COSV100054170, COSV58625430; called by muse, mutect2
- NPC1 | c.2485C>G p.L829V | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as COSV52581780; called by muse, mutect2
- NPC1 | c.2213C>T p.S738L | Missense Mutation (SNP) | VAF 14/203 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs777286835, CM032636, COSV52581793; called by muse, mutect2
- NPFFR2 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV58152682; called by muse, mutect2, varscan2
- NRXN3 | c.2076G>C p.M692I (on ENST00000335750 / NM_001330195.2; = p.M319I on NM_004796.6) | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV59785970; called by muse, mutect2, varscan2
- NSUN6 | c.27G>C p.L9F | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV66034522; called by muse, mutect2, varscan2
- NT5C3A | c.269G>C p.R90T (on ENST00000610140 / NM_001374335.1; = p.R56T on NM_016489.13) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV54239651; called by muse, mutect2, varscan2
- ODAM | c.227C>G p.S76C | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1019560574, COSV101258041, COSV68573311; called by muse, mutect2, varscan2
- OGDHL | c.2617G>C p.E873Q | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV65103889; called by muse, mutect2, varscan2
- OR13F1 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs749098772, COSV58252276; called by muse, mutect2, varscan2
- OR2M7 | c.58C>G p.H20D | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.934); catalogued as COSV58740095; called by muse, mutect2
- OR5T1 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 108/286 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV57304130; called by muse, mutect2, varscan2
- OR8B12 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV60912408; called by muse, mutect2, varscan2
- PABPN1 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as COSV53730069; called by muse, mutect2, varscan2
- PADI4 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV64924577; called by muse, mutect2, varscan2
- PAPPA2 | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV62806610; called by muse, mutect2
- PAXBP1 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV51611359; called by muse, mutect2
- PCDH8 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.84); PolyPhen benign (0.053); catalogued as COSV100132082; called by muse, mutect2
- PCDHA8 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 51/89 reads (57%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as rs376777545, COSV100969187; called by muse, mutect2, varscan2
- PCSK7 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58008858; called by muse, mutect2, varscan2
- PDE4DIP | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288801467, COSV100519774, COSV57718114; called by mutect2, varscan2
- PDLIM3 | c.565G>A p.D189N (on ENST00000284770 / NM_001257963.1; = p.D356N on NM_014476.6) | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV52980644; called by muse, mutect2, varscan2
- PHF3 | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as COSV50330957; called by muse, mutect2, varscan2
- PHLDB2 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV67314620; called by muse, mutect2, varscan2
- PLA2G2E | c.152C>G p.S51C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV64290821; called by muse, mutect2, varscan2
- PLEKHA3 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV52295829; called by muse, mutect2, varscan2
- PLK3 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV59499057; called by muse, mutect2
- PMVK | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63786059; called by muse, mutect2, varscan2
- POGK | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1237575821, COSV63312091; called by muse, mutect2, varscan2
- POLH | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV64780559; called by muse, mutect2
- PORCN | c.736G>A p.E246K (on ENST00000326194 / NM_203475.3; = p.E235K on NM_022825.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV58225405; called by muse, mutect2, varscan2
- POTEF | c.1652G>C p.G551A | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.031); catalogued as COSV62543073; called by muse, mutect2, varscan2
- PPP1R3A | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as COSV52889331; called by muse, mutect2, varscan2
- PRKCB | c.1982C>G p.S661C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57787793; called by muse, mutect2, varscan2
- PSG7 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 50/354 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV68446114; called by muse, varscan2
- PSG7 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 30/715 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs782714316, COSV68445709; called by muse, mutect2
- PSIP1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV66255355; called by muse, mutect2, varscan2
- PSMA1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV67166126; called by muse, mutect2, varscan2
- PSMC1 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54321692; called by muse, mutect2, varscan2
- PTCH1 | c.3959G>A p.R1320K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.053); catalogued as COSV59487160; called by muse, mutect2, varscan2
- PTCH1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as CM070247, CM152924, COSV59487196; called by muse, mutect2, varscan2
- PTGER3 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.108); catalogued as COSV63040696; called by muse, mutect2
- PTPRD | c.3403G>A p.E1135K | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.084); catalogued as COSV61971300; called by muse, mutect2
- PTPRD | c.1369A>G p.M457V | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.06); catalogued as rs372854730; called by muse, mutect2, varscan2
- PTPRK | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV63894453, COSV63903892; called by muse, mutect2, varscan2
- PTPRN2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67031683; called by muse, mutect2, varscan2
- RARG | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58433820; called by muse, mutect2, varscan2
- RBBP5 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV52706076; called by muse, mutect2, varscan2
- RELN | c.4687G>A p.D1563N | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs759018172, COSV59024327; called by muse, mutect2, varscan2
- RHOT1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61715544, COSV61717591; called by muse, mutect2, varscan2
- RRAS | c.635G>A p.G212D | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV55868923; called by muse, varscan2
- SAMD11 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV58990044; called by muse, varscan2
- SAMD4A | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as rs200776549, COSV51885885; called by muse, mutect2, varscan2
- SCAF11 | c.3395C>T p.S1132L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1199074511, COSV65478258; called by muse, mutect2, varscan2
- SCAF4 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as COSV54590660; called by muse, varscan2
- SCAPER | c.3666C>A p.F1222L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV57748596; called by muse, mutect2, varscan2
- SCN4A | c.3203C>T p.A1068V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1204423533; called by muse, mutect2
- SCRIB | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1424850563, COSV57591324; called by muse, mutect2
- SEPTIN10 | c.556C>G p.L186V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs1558788905, COSV61781422, COSV61782052; called by muse, mutect2, varscan2
- SF3A1 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53170536; called by muse, mutect2
- SFXN4 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV53720216; called by muse, mutect2, varscan2
- SHANK1 | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV53257996; called by muse, mutect2, varscan2
- SHPRH | c.3820G>A p.E1274K (on ENST00000275233 / NM_001042683.3; = p.E1278K on NM_173082.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV51615061; called by muse, mutect2, varscan2
- SLC17A6 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as rs768950841, COSV54138350; called by muse, mutect2, varscan2
- SLC24A2 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV53871562; called by muse, mutect2
- SLC25A16 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as rs1236764946, COSV56264924; called by muse, mutect2, varscan2
- SLC25A27 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64928452; called by muse, mutect2, varscan2
- SLC27A3 | c.791G>A p.G264E (on ENST00000271857; = p.G136E on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs559005134, COSV55165075; called by muse, mutect2, varscan2
- SLC2A10 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867914135, COSV63715651; called by muse, mutect2, varscan2
- SLF2 | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53277324; called by muse, mutect2, varscan2
- SLX4 | c.2848G>C p.E950Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.157); catalogued as COSV53565104, COSV53566925; called by muse, mutect2, varscan2
- SMARCA1 | c.2752C>G p.Q918E | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.867); catalogued as rs751134240, COSV64413204; called by muse, mutect2, varscan2
- SMARCA2 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.055); catalogued as COSV61810671; called by muse, mutect2, varscan2
- SMARCB1 | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV53157387; called by muse, varscan2
- SNAP25 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.304); catalogued as COSV54774489; called by muse, mutect2, varscan2
- SNX7 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV60270730; called by muse, mutect2
- SORBS1 | c.3254C>T p.S1085L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1475396735, COSV53362523, COSV99528223; called by muse, mutect2, varscan2
- SORBS1 | c.2660C>T p.S887F (on ENST00000361941 / NM_001034954.2; = p.S537F on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53362532; called by muse, mutect2
- SP100 | c.992C>G p.S331C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV50993887; called by muse, mutect2, varscan2
- SPIN2A | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as COSV66520316, COSV66520671; called by muse, mutect2, varscan2
- SPTBN2 | c.5968C>T p.Q1990* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs1289861297; called by muse, mutect2
- SRRM2 | c.7067G>A p.R2356K | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV51941481; called by muse, varscan2
- STRBP | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100724034; called by muse, mutect2
- SYTL2 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.184); catalogued as COSV60361818; called by muse, varscan2
- SYTL2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60361841; called by muse, mutect2, varscan2
- TACR1 | c.659G>A p.G220E | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59484500; called by muse, mutect2, varscan2
- TASOR2 | c.3742G>A p.E1248K | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as rs753189041, COSV60168860; called by muse, mutect2, varscan2
- TBC1D8B | c.808C>G p.P270A | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV52181949, COSV52183556; called by muse, mutect2, varscan2
- TENM3 | c.275C>A p.A92E | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.001); catalogued as COSV69315207; called by muse, mutect2, varscan2
- TENT4A | c.1814C>T p.S605L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV50098161; called by muse, mutect2, varscan2
- TENT5A | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as COSV60788968; called by muse, mutect2, varscan2
- TFAP2A | c.578C>T p.S193F (on ENST00000482890; = p.S185F on NM_001032280.3) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV60232811, COSV60236395; called by muse, mutect2, varscan2
- TFEC | c.97C>G p.L33V | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV55404792; called by muse, mutect2, varscan2
- TGM2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs776311789, COSV63932097; called by muse, mutect2, varscan2
- TGOLN2 | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 230/638 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.975); catalogued as rs976929094, COSV56407088; called by muse, mutect2, varscan2
- TIGD4 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV58550505, COSV58550989; called by muse, mutect2, varscan2
- TKTL1 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV54211580; called by muse, mutect2
- TMCC1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV67874213; called by muse, mutect2, varscan2
- TMCO3 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as rs1467717829, COSV64808629; called by muse, mutect2, varscan2
- TMEM130 | c.1099C>G p.Q367E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV59560354; called by muse, mutect2, varscan2
- TMEM175 | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV53280368; called by muse, mutect2
- TNPO1 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV61523237; called by muse, mutect2, varscan2
- TNPO3 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as COSV55285059; called by muse, mutect2, varscan2
- TOP3A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV58179995; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54871130; called by muse, mutect2
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- TRERF1 | c.3526G>A p.E1176K | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV61675779; called by muse, mutect2
- TRHDE | c.1864G>C p.D622H | Missense Mutation (SNP) | VAF 63/106 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53837287, COSV53857836; called by muse, mutect2, varscan2
- TRIM27 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV65873887; called by muse, mutect2, varscan2
- TRIM59 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59088116; called by muse, mutect2, varscan2
- TRPV6 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV63892973; called by muse, mutect2, varscan2
- TSNARE1 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV56180968; called by muse, mutect2, varscan2
- TSSK1B | c.280G>A p.V94I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.216); catalogued as COSV66815772; called by muse, mutect2, varscan2
- TTBK2 | c.2794G>A p.D932N | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV51171046; called by muse, mutect2, varscan2
- TTN | c.83145G>T p.W27715C (on ENST00000591111; = p.W20291C on NM_003319.4) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | PolyPhen probably damaging (0.999); catalogued as COSV100629444, COSV60240404; called by muse, mutect2, varscan2
- TTN | c.5115C>G p.F1705L (on ENST00000591111; = p.F1659L on NM_003319.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | PolyPhen probably damaging (0.987); catalogued as rs375828531; called by muse, mutect2, varscan2
- UIMC1 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.351); catalogued as rs762592340, COSV101022194, COSV65895160; called by muse, mutect2
- USP4 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV55539366; called by muse, mutect2
- USP9X | c.1492G>A p.D498N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61073176; called by muse, mutect2
- UTP14C | c.2225C>T p.S742L | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as COSV73000766; called by muse, mutect2
- VGF | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.08); catalogued as rs1020444087, COSV99972819; called by muse, mutect2
- VIPAS39 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs775051184, COSV58941342; called by muse, mutect2, varscan2
- VSTM1 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs1348498789, COSV58075724, COSV58076104; called by muse, mutect2, varscan2
- WIPF3 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771897351, COSV54206995; called by muse, mutect2, varscan2
- WWP2 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.529); catalogued as rs372517256; called by muse, mutect2, varscan2
- XPO5 | c.1518G>A p.M506I | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV104373603; called by muse, mutect2
- XPO5 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV54833373; called by muse, mutect2, varscan2
- ZAN | c.7175T>A p.I2392N | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV100768931; called by muse, mutect2
- ZAN | c.8338G>C p.E2780Q | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV61813051; called by muse, mutect2, varscan2
- ZBTB38 | c.1967G>T p.G656V | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV58543502; called by muse, mutect2, varscan2
- ZC3H14 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51772172; called by muse, mutect2, varscan2
- ZC3H4 | c.3715G>A p.E1239K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.27); catalogued as rs568440265; called by muse, mutect2
- ZFHX4 | c.7072C>T p.Q2358* | Nonsense Mutation (SNP) | VAF 32/176 reads (18%) | catalogued as COSV99254814; called by muse, mutect2, varscan2
- ZNF10 | c.782G>C p.R261T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.333); catalogued as COSV50213817; called by muse, mutect2, varscan2
- ZNF202 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV60248036; called by muse, mutect2, varscan2
- ZNF230 | c.561G>C p.Q187H | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV71273615; called by muse, mutect2, varscan2
- ZNF276 | c.1393C>T p.R465W (on ENST00000443381 / NM_001113525.2; = p.R390W on NM_152287.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs764775504, COSV57071205; called by muse, varscan2
- ZNF280A | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV57481672; called by muse, mutect2
- ZNF479 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.337); catalogued as rs551129651, COSV100482333, COSV100482422; called by muse, mutect2, varscan2
- ZNF585B | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV57216388; called by muse, mutect2, varscan2
- ZNF687 | c.2779G>A p.E927K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.051); catalogued as rs1311402866; called by muse, mutect2
- ZNF799 | c.494G>C p.G165A | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as COSV70123175; called by muse, mutect2
- ZPBP2 | c.292G>C p.D98H (on ENST00000348931 / NM_199321.3; = p.D76H on NM_198844.3) | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV62375539; called by muse, mutect2, varscan2
- ZSCAN9 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178338337, COSV52850619; called by muse, mutect2
- ACACA | c.1775C>G p.S592C | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALDH9A1 | c.803C>A p.S268* | Nonsense Mutation (SNP) | VAF 29/197 reads (15%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7369C>T p.Q2457* | Nonsense Mutation (SNP) | VAF 45/173 reads (26%) | called by muse, mutect2, varscan2
- ARPC3 | c.255C>T p.C85= | Splice Region (SNP) | VAF 8/39 reads (21%) | called by muse, varscan2
- CACNA2D1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2
- CARD6 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.4468G>C p.E1490Q | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBWD2 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0); called by mutect2, varscan2
- CHD1 | c.4904C>G p.S1635* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- CHD5 | c.4852C>T p.R1618* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- CNST | c.938-1G>A p.X313_splice | Splice Site (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2
- DLGAP3 | c.2764C>T p.R922W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- EFCAB11 | c.185C>T p.S62F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- EIF4E | c.571C>G p.P191A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRY | c.7168C>G p.Q2390E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2
- GABRA5 | c.1144A>G p.M382V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALC | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- GLI4 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); called by muse, mutect2
- GPR173 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GSTM3 | c.395T>A p.L132* | Nonsense Mutation (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- HIP1R | c.2851del p.A951Pfs*26 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | called by mutect2, pindel, varscan2
- IGHV3-23 | c.167T>A p.V56D | Missense Mutation (SNP) | VAF 76/356 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- IL27RA | c.1464G>A p.W488* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- INSL5 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.409); called by muse, mutect2
- KIAA2026 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- KLHL41 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 48/152 reads (32%) | called by muse, mutect2, varscan2
- MOCS3 | c.1181G>A p.W394* | Nonsense Mutation (SNP) | VAF 92/231 reads (40%) | called by muse, mutect2, varscan2
- MYLIP | c.746_757delinsGA p.I249Rfs*4 | Frame Shift Del (DEL) | VAF 64/176 reads (36%) | called by pindel, varscan2*
- NCOA4 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PATJ | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- PCNX3 | c.3349C>T p.P1117S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2
- RPL23A | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SACS | c.2767_2769dup p.E923dup | In Frame Ins (INS) | VAF 38/119 reads (32%) | called by mutect2, pindel, varscan2
- SPDYE5 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2
- SPTY2D1 | c.1217C>G p.S406* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- SSH3 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAF7L | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- TFAP2E | c.1033C>A p.L345M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP33 | c.2292del p.L765Ffs*20 | Frame Shift Del (DEL) | VAF 40/128 reads (31%) | called by mutect2, pindel, varscan2
- ZNF133 | c.1688C>G p.S563* (on ENST00000316358 / NM_001352454.2; = p.S562* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- ZNF208 | c.1145C>G p.S382* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- ZNF790 | c.696del p.K233Sfs*121 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- ZPBP2 | c.190G>T p.E64* (on ENST00000348931 / NM_199321.3; = p.E42* on NM_198844.3) | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- A2M | c.3303C>T p.L1101= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV59390619; called by muse, mutect2, varscan2
- ADAMTS15 | c.171C>T p.I57= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV54508466; called by muse, mutect2, varscan2
- AHNAK2 | c.14904G>A p.K4968= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV60924506; called by muse, mutect2, varscan2
- AKT1 | c.205C>A p.R69= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100838135, COSV62575169; called by muse, mutect2, varscan2
- ALDH1A2 | c.1020C>T p.S340= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as rs114347273; called by muse, mutect2
- ALDH5A1 | c.1327C>T p.L443= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV62374314; called by muse, mutect2, varscan2
- ANK2 | c.6894G>A p.E2298= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV52178764; called by muse, mutect2, varscan2
- ANXA11 | c.30A>G p.P10= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as COSV55417744; called by muse, mutect2, varscan2
- ARFGEF3 | c.3681G>A p.Q1227= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV52466068; called by muse, mutect2, varscan2
- ARHGAP25 | c.933C>T p.D311= (on ENST00000409202 / NM_001007231.3; = p.D303= on NM_014882.3) | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV54906112; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.834C>T p.I278= | Silent (SNP) | VAF 23/81 reads (28%) | catalogued as rs745320736, COSV63438689; called by muse, mutect2, varscan2
- ARMH4 | c.1263C>T p.F421= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV50769282; called by muse, varscan2
- AVEN | c.862C>T p.L288= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as COSV60736592; called by muse, mutect2, varscan2
- BMX | c.571C>T p.L191= | Silent (SNP) | VAF 85/109 reads (78%) | catalogued as COSV59592656; called by muse, mutect2, varscan2
- BRPF1 | c.544C>A p.R182= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs1247866384, COSV57406846; called by muse, mutect2, varscan2
- BVES | c.334T>C p.L112= | Silent (SNP) | VAF 21/67 reads (31%) | called by muse, mutect2
- C16orf71 | c.1458G>A p.Q486= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs767807614, COSV54789348, COSV99556451; called by muse, mutect2, varscan2
- CACNG1 | c.591C>T p.L197= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs762591486, COSV56827455; called by muse, mutect2, varscan2
- CCDC191 | c.1620C>T p.T540= | Silent (SNP) | VAF 9/260 reads (3%) | catalogued as COSV55674884; called by muse, mutect2
- CCDC87 | c.153G>A p.A51= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as rs1429236863, COSV59580020; called by muse, mutect2
- CCHCR1 | c.1287G>A p.L429= | Silent (SNP) | VAF 7/168 reads (4%) | catalogued as COSV66184713; called by muse, mutect2
- CES3 | c.774C>T p.I258= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV57593621; called by muse, mutect2, varscan2
- CHIA | c.1170G>A p.Q390= (on ENST00000343320; = p.Q282= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV58477220; called by muse, mutect2, varscan2
- CIAO3 | c.753G>T p.L251= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV52403711; called by muse, mutect2
- CLASP1 | c.3922C>T p.L1308= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- COG3 | c.2295G>A p.L765= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as COSV63074309; called by muse, mutect2, varscan2
- COMMD9 | c.147C>T p.S49= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV54673012; called by muse, mutect2
- CRTC2 | c.1293C>A p.P431= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV57844922; called by muse, mutect2, varscan2
- CSNK1G2 | c.120G>A p.L40= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV55338863, COSV55339276; called by muse, mutect2, varscan2
- CYP3A5 | c.1344C>G p.L448= | Silent (SNP) | VAF 9/194 reads (5%) | catalogued as COSV56121465; called by muse, mutect2
- CYP4A11 | c.111C>T p.L37= | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- DAB1 | c.990C>T p.P330= (on ENST00000371231; = p.P297= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- DENND1A | c.2937G>A p.Q979= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV65354258; called by muse, mutect2, varscan2
- DKKL1 | c.135C>G p.L45= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV55561924, COSV55563133; called by muse, mutect2
- DLL4 | c.1593C>T p.A531= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs544067517, COSV51068095; called by muse, mutect2, varscan2
- DNAAF1 | c.930G>A p.E310= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs752852857, COSV57578363; called by muse, mutect2
- DNAH3 | c.3480G>A p.L1160= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV54540180; called by muse, mutect2, varscan2
- DNAI2 | c.924C>T p.I308= | Silent (SNP) | VAF 66/152 reads (43%) | catalogued as COSV56761409; called by muse, mutect2, varscan2
- DNASE1L3 | c.138G>A p.V46= | Silent (SNP) | VAF 13/366 reads (4%) | catalogued as COSV59157025; called by muse, mutect2
- DRD5 | c.201G>A p.R67= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100432036, COSV58579606; called by muse, varscan2
- DRD5 | c.267C>T p.F89= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs975877349, COSV58579305; called by muse, varscan2
- ELOVL3 | c.126G>A p.L42= | Silent (SNP) | VAF 4/91 reads (4%) | called by muse, mutect2
- ENTHD1 | c.1674G>A p.A558= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs368803554; called by muse, mutect2, varscan2
- EPB41L4B | c.393C>T p.L131= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs761043621, COSV65798186; called by muse, mutect2, varscan2
- EPRS1 | c.216G>A p.L72= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as rs757645661, COSV65099615, COSV65100759; called by muse, mutect2, varscan2
- FN1 | c.2823G>A p.V941= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV60559891; called by muse, mutect2, varscan2
- FOXD4L1 | c.465C>T p.I155= | Silent (SNP) | VAF 18/478 reads (4%) | catalogued as COSV99380053; called by muse, mutect2
- FRMPD2 | c.1032C>T p.L344= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV100563737; called by muse, mutect2
- GAP43 | c.384T>C p.P128= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV59346980; called by muse, mutect2, varscan2
- GDF2 | c.996G>A p.L332= | Silent (SNP) | VAF 16/110 reads (15%) | called by muse, mutect2, varscan2
- GGT5 | c.1065G>A p.E355= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs375177073, COSV54071815; called by muse, mutect2, varscan2
- GIPC1 | c.303C>T p.T101= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV61774950; called by muse, mutect2
- GP5 | c.1668G>A p.E556= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as COSV59879576; called by muse, mutect2, varscan2
- GPR37L1 | c.1101C>T p.V367= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV66162659; called by muse, mutect2
- GRM5 | c.861G>A p.L287= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV59611198; called by muse, mutect2, varscan2
- GRTP1 | c.231C>A p.V77= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV58151404; called by muse, varscan2
- GTF3C3 | c.565C>T p.L189= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV55833754; called by muse, mutect2, varscan2
- H2BC6 | c.69G>A p.Q23= | Silent (SNP) | VAF 62/188 reads (33%) | catalogued as COSV61591543; called by muse, mutect2
- HELZ2 | c.6087C>T p.L2029= (on ENST00000467148 / NM_001037335.2; = p.L1460= on NM_033405.3) | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs776883983, COSV71296636; called by muse, mutect2, varscan2
- HIVEP3 | c.1296G>A p.L432= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV56020560; called by muse, mutect2, varscan2
- HNRNPK | c.915G>T p.R305= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV61090505; called by muse, varscan2
- IGHV3-33 | c.117C>T p.L39= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs745448214; called by muse, mutect2, varscan2
- IL17RE | c.219C>T p.V73= | Silent (SNP) | VAF 56/184 reads (30%) | catalogued as COSV55969825; called by muse, mutect2, varscan2
- KCNJ9 | c.252C>T p.Y84= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- KIF20B | c.250C>T p.L84= | Silent (SNP) | VAF 63/113 reads (56%) | catalogued as COSV53312624; called by muse, mutect2, varscan2
- KRT78 | c.264C>T p.I88= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV58852976; called by muse, mutect2, varscan2
- L1CAM | c.729C>T p.L243= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs782492763; called by muse, mutect2
- LIM2 | c.126G>A p.L42= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as COSV55741815; called by muse, mutect2, varscan2
- LRAT | c.411C>G p.L137= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs572457198, COSV60477785; called by muse, mutect2, varscan2
- LRP1B | c.5364G>A p.K1788= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV67275995; called by muse, mutect2
- LRP8 | c.330G>A p.E110= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV60100449; called by muse, mutect2, varscan2
- MAGEH1 | c.528C>T p.V176= | Silent (SNP) | VAF 45/62 reads (73%) | catalogued as COSV61679076; called by muse, mutect2, varscan2
- MAST4 | c.822A>G p.S274= (on ENST00000403625 / NM_001164664.2; = p.S85= on NM_015183.3) | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs371008871; called by muse, mutect2, varscan2
- MDN1 | c.7692C>G p.L2564= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as COSV65527214; called by muse, mutect2, varscan2
- MET | c.1521G>A p.G507= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV59266076; called by muse, mutect2
- MOCS3 | c.153G>A p.P51= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as COSV54867400; called by muse, mutect2
- MOK | c.72G>C p.L24= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV51966772; called by muse, mutect2, varscan2
- MPL | c.561G>A p.L187= | Silent (SNP) | VAF 43/123 reads (35%) | catalogued as COSV65246201; called by muse, mutect2, varscan2
- MRM1 | c.741C>T p.L247= | Silent (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- MROH9 | c.930T>C p.C310= | Silent (SNP) | VAF 69/181 reads (38%) | catalogued as COSV63012620; called by muse, mutect2, varscan2
- MROH9 | c.1356G>C p.L452= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV63012623; called by muse, mutect2
- MX2 | c.762G>A p.Q254= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as COSV58098393; called by muse, mutect2, varscan2
- MYBBP1A | c.567G>A p.S189= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs377058397; called by muse, mutect2, varscan2
- MYT1L | c.624C>T p.L208= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs561075867, COSV67717716; called by muse, mutect2, varscan2
- NAPSA | c.606G>A p.P202= | Silent (SNP) | VAF 40/117 reads (34%) | catalogued as rs200603901, COSV53798505; called by muse, mutect2, varscan2
- NUDT6 | c.36G>C p.A12= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV56773884, COSV56781258; called by muse, mutect2, varscan2
- OR10R2 | c.717C>T p.L239= | Silent (SNP) | VAF 16/146 reads (11%) | catalogued as COSV63769285; called by muse, mutect2
- OSBPL7 | c.165C>T p.L55= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV104375277; called by muse, mutect2
- PANK2 | c.189G>A p.P63= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- PCDHA1 | c.270C>T p.I90= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV65374396; called by muse, mutect2
- PCDHB13 | c.1077G>A p.E359= | Silent (SNP) | VAF 9/211 reads (4%) | catalogued as COSV53394588; called by muse, mutect2
- PCM1 | c.1380C>T p.S460= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV61518236; called by muse, mutect2
- PHLDB2 | c.810C>G p.L270= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV67314628; called by muse, mutect2, varscan2
- PLCB4 | c.3483G>A p.V1161= (on ENST00000278655 / NM_182797.3; = p.E1174K on NM_000933.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as rs760861010, COSV53801899; called by muse, mutect2, varscan2
- PLEKHG3 | c.795C>T p.F265= (on ENST00000394691; = p.F321= on NM_001308147.2) | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs866432130, COSV55982327; called by muse, mutect2, varscan2
- PLEKHM1 | c.3170G>A p.*1057= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs1237354296; called by muse, mutect2, varscan2
- POMGNT2 | c.426C>T p.F142= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as COSV60954344; called by muse, mutect2, varscan2
- PTAFR | c.51C>A p.L17= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV59536239, COSV59537774; called by muse, mutect2, varscan2
- PTCD3 | c.1911C>T p.F637= | Silent (SNP) | VAF 28/200 reads (14%) | catalogued as rs746423190, COSV54482074; called by muse, mutect2, varscan2
- PTGDS | c.144C>T p.L48= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- RDM1 | c.459G>A p.P153= | Silent (SNP) | VAF 32/115 reads (28%) | catalogued as rs373207074; called by muse, mutect2, varscan2
- RIN1 | c.1737G>A p.L579= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100254289; called by muse, mutect2
- RNF8 | c.769C>T p.L257= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV57721988; called by muse, mutect2, varscan2
- S1PR1 | c.441G>A p.L147= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as COSV59514028; called by muse, mutect2, varscan2
- SCN4A | c.4674G>A p.E1558= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs778996581, COSV71128252; called by muse, mutect2, varscan2
- SEMA4G | c.1638G>C p.L546= (on ENST00000370250; = p.L551= on NM_017893.3) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV52970743; called by muse, mutect2, varscan2
- SERPINA7 | c.19C>T p.L7= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV59666827; called by muse, mutect2
- SHB | c.1314G>A p.Q438= | Silent (SNP) | VAF 7/79 reads (9%) | catalogued as COSV66630016; called by muse, mutect2
- SIPA1 | c.1080C>T p.F360= | Silent (SNP) | VAF 28/149 reads (19%) | catalogued as COSV67746277; called by muse, mutect2, varscan2
- SLC7A9 | c.981C>T p.L327= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV50089687; called by muse, mutect2, varscan2
- SLCO1C1 | c.1851C>T p.L617= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV56877156; called by muse, mutect2, varscan2
- SPHKAP | c.4428G>A p.V1476= | Silent (SNP) | VAF 25/144 reads (17%) | catalogued as rs1410252568, COSV60889624; called by muse, mutect2, varscan2
- STX17 | c.621C>T p.V207= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV52285183; called by muse, mutect2, varscan2
- STXBP3 | c.1284G>A p.Q428= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV64183142; called by muse, mutect2
- SV2B | c.1014C>G p.S338= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as rs367942173; called by muse, mutect2, varscan2
- TASP1 | c.699C>T p.D233= | Silent (SNP) | VAF 37/156 reads (24%) | catalogued as COSV61814894; called by muse, mutect2, varscan2
- TMEM87B | c.1386C>T p.F462= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV51712700; called by muse, mutect2
- TPCN2 | c.945C>T p.F315= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1179839511, COSV53732429; called by muse, mutect2, varscan2
- TRIM16 | c.1452G>A p.E484= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs1354550130, COSV60887842; called by muse, mutect2, varscan2
- TRIM25 | c.177G>A p.A59= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- TRPM1 | c.918C>T p.L306= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs1327026756, COSV56639328; called by muse, mutect2
- TSPOAP1 | c.126C>T p.I42= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs148586326; called by mutect2, varscan2
- TULP4 | c.96G>A p.E32= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1393842106; called by muse, mutect2, varscan2
- UBE3C | c.2253G>A p.R751= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as COSV61953189, COSV61954993; called by muse, mutect2
- UGT2B4 | c.810C>G p.L270= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV59315491, COSV59321298; called by muse, mutect2
- VIRMA | c.157C>T p.L53= | Silent (SNP) | VAF 43/229 reads (19%) | catalogued as COSV52589106; called by muse, mutect2, varscan2
- VIT | c.510G>A p.Q170= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV64898365; called by muse, mutect2, varscan2
- VSIG1 | c.825A>G p.E275= | Silent (SNP) | VAF 53/73 reads (73%) | catalogued as COSV54261297; called by muse, mutect2, varscan2
- ZBTB22 | c.627C>T p.F209= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV56471671; called by muse, mutect2, varscan2
- ZNF276 | c.1464C>T p.L488= (on ENST00000443381 / NM_001113525.2; = p.L413= on NM_152287.4) | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1231189137, COSV57071226; called by muse, varscan2
- ZNF479 | c.636C>T p.S212= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100482329; called by muse, mutect2, varscan2
- ZNF587 | c.1185C>T p.L395= | Silent (SNP) | VAF 106/241 reads (44%) | catalogued as rs146642070; called by muse, mutect2, varscan2
- ZNF777 | c.2013G>A p.K671= | Silent (SNP) | VAF 30/170 reads (18%) | catalogued as rs756086880, COSV56099381; called by muse, mutect2, varscan2
- ZNF804A | c.3105G>A p.L1035= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV56462836, COSV56465942; called by muse, mutect2, varscan2
- CBX2 | c.288+66G>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as COSV53969858; called by muse, mutect2, varscan2
- CLCA3P | n.514G>C | RNA (SNP) | VAF 5/119 reads (4%) | called by muse, mutect2
- IGLL3P | n.60C>T | RNA (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- KRT4 | c.-8C>G | 5'UTR (SNP) | VAF 18/51 reads (35%) | catalogued as COSV53408965; called by muse, mutect2, varscan2
- LIN54 | c.-1C>T | 5'UTR (SNP) | VAF 65/137 reads (47%) | catalogued as COSV100464104; called by muse, mutect2, varscan2
- MACF1 | c.16491+455G>A | Intron (SNP) | VAF 5/73 reads (7%) | catalogued as COSV57135495; called by muse, mutect2
- MRPL43 | c.529-2167C>T | Intron (SNP) | VAF 20/93 reads (22%) | catalogued as COSV52970751; called by muse, mutect2, varscan2
- RERE | c.830+15436G>T | Intron (SNP) | VAF 11/15 reads (73%) | catalogued as COSV61947338; called by muse, mutect2, varscan2
- SERPINA13P | n.743G>A | RNA (SNP) | VAF 65/163 reads (40%) | catalogued as rs1019416850; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928697 G>C | 3'Flank (SNP) | VAF 12/66 reads (18%) | catalogued as COSV60487972; called by muse, mutect2, varscan2
- SNORD116-11 | n.42G>A | RNA (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- TKTL1 | c.1402-170C>T | Intron (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99473603; called by muse, mutect2
